Gene-level copy-number profile of tumor specimen TCGA-AC-A3QQ-01A from TCGA case TCGA-AC-A3QQ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 54.0 years (19,723 days).
Specimen TCGA-AC-A3QQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.25dbaee9-17b6-4279-94ec-99b5b97e14e9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AC-A3QQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c02b6efc-ebc9-4dca-907f-383ebb0da9f1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,292; copy number 2: 49,162; copy number 3: 3,457; copy number 4: 116; copy number 5: 2,537; copy number 6: 17; copy number 7: 62; copy number 8: 36; copy number 12: 39; copy number 14: 45; copy number 16: 20; copy number 23: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AC-A3QQ-01A-11D-A227-01): tumor purity 0.71, ploidy 2.09, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,791 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–179,691,272, 1,199 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr1:182,899,865–248,919,946, 1,338 genes, copy number 5 (broad region; genes not listed).
- chr11:69,414,307–70,398,488, 32 genes, copy number 8–16: AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1.
- chr17:27,089,545–27,352,828, 9 genes, copy number 6 (within-gene range 3–6): AC129926.2, AC129926.1, RPL34P31, RPS16P8, AC026254.1, MIR4522, WSB1, AC026254.2, SYPL1P2.
- chr17:33,052,107–33,131,743, 3 genes, copy number 6: AC003687.1, AC008133.2, AC008133.1.
- chr17:35,147,817–37,609,472, 118 genes, copy number 6–12 (within-gene range 3–12) (broad region; genes not listed).
- chr17:38,914,979–40,809,296, 92 genes, copy number 7–23 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,292. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
